Somatic mutation profile of tumor specimen TARGET-10-PARURK-09A (aliquot TARGET-10-PARURK-09A-01D) from TARGET case TARGET-10-PARURK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,912 days).
Specimen TARGET-10-PARURK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b290b95-9e0a-40b0-aff9-9599b7a41f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARURK-14A (Bone Marrow Normal), aliquot TARGET-10-PARURK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/245411b5-5731-47c0-af89-3fccc77dbb95

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- COL4A5 | c.4265G>A p.R1422H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV60355533; called by muse, mutect2, varscan2
- COL6A3 | c.9214G>A p.G3072R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1397014474, COSV99795717; called by muse, mutect2, varscan2
- KCNJ16 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs758696762, COSV52252322; called by muse, mutect2, varscan2
- MYH2 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 7/189 reads (4%) | catalogued as COSV55435229; called by muse, mutect2
- SCARB1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs753772380; called by muse, mutect2, varscan2
- SFR1 | c.274G>A p.E92K (on ENST00000369727 / NM_001002759.1; = p.E79K on NM_145247.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1248982953; called by muse, mutect2, varscan2
- ANKRD2 | c.509A>T p.D170V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- RUNX1T1 | c.464T>A p.L155Q (on ENST00000265814 / NM_001198628.1; = p.L128Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPV3 | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PSAPL1 | c.378G>A p.P126= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs772342346, COSV100040512; called by muse, mutect2, varscan2
- LRP1B | c.13561-31T>A | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2
- MYO9B | c.2373+57C>G | Intron (SNP) | VAF 53/137 reads (39%) | called by muse, mutect2, varscan2
- ZAP70 | c.889+33G>A | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
